Surgical pathology report (de-identified scan), TCGA case TCGA-XV-AAZW, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Capital Biosciences, specimen TCGA-XV-AAZW-01A (Primary Tumor).

Pathology Report

Date:

Patient ID:

Age:

Sex:

F

Clinical Dx:

Mixed-cell Melanoma

Tumor Location:

Skin

Localization:

Left femur

Source:

Epithelial melanoma

Clark Level (1-5):

5

Breslow (mm):

14

Tumor:

4

Normal:

0

Metastasis:

0

Stage (I-IV):

II

Tumor size (mm x mm):

10x13

NeoAdj ImmunoTx:

No

ICD-O.3
Melanoma NOS 8720/3
Site Neg NOS C44.7
JW 3/12/14

Source: NCI Genomic Data Commons file 84c256ad-5511-4293-9bf6-c29f6baf30cb (TCGA-XV-AAZW.D95D24B2-4A20-4C7B-963A-3C7F89CAA6BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).